Somatic mutation profile of tumor specimen MP2PRT-PAPTRY-TMP1-A (aliquot MP2PRT-PAPTRY-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPTRY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,470 days).
Specimen MP2PRT-PAPTRY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c0ee311-2d8d-4215-a26f-34bbf7804901.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPTRY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPTRY-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7a5041f-9f29-4c74-b98b-f2e22eaa904c

The open-access MAF lists 29 somatic variants for this specimen: 18 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 14, Silent 11, Nonsense Mutation 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV1 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 24/258 reads (9%) | catalogued as COSV54150825; called by muse, mutect2
- ETV1 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 11/274 reads (4%) | catalogued as COSV99623484; called by muse, mutect2
- NKAPD1 | c.412C>T p.P138S (on ENST00000280352 / NM_001082970.2; = p.P139S on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.324); catalogued as COSV54778028; called by muse, mutect2, varscan2
- OR13C5 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 167/260 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs746195802, COSV66164500, COSV66164505; called by muse, mutect2, varscan2
- RYR1 | c.12335C>T p.S4112L | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs193922847, CM071983, COSV62087989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT8 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.187); catalogued as COSV60416153; called by muse, mutect2
- ZNF215 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 133/326 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs751369345; called by muse, varscan2
- ZNF532 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 169/405 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs373691715; called by muse, mutect2, varscan2
- CEP120 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- COL4A1 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 53/355 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC4 | c.1484A>G p.N495S | Missense Mutation (SNP) | VAF 13/325 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2
- FRG2 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 54/452 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGHV3-53 | c.349_350insGCCCGGGGG | In Frame Ins (INS) | VAF 24/34 reads (71%) | called by pindel, varscan2
- JUNB | c.718A>T p.K240* | Nonsense Mutation (SNP) | VAF 22/648 reads (3%) | called by muse, mutect2
- LRP1B | c.587A>T p.K196I | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- NME8 | c.1070A>G p.E357G | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- RLF | c.513C>G p.N171K | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- UBA2 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GRIN2A | c.3051C>T p.S1017= | Silent (SNP) | VAF 127/313 reads (41%) | catalogued as rs773366584, COSV58020301; called by muse, mutect2, varscan2
- HECW1 | c.2427G>A p.Q809= | Silent (SNP) | VAF 14/316 reads (4%) | called by muse, mutect2
- KSR2 | c.753G>A p.S251= | Silent (SNP) | VAF 274/555 reads (49%) | catalogued as rs372935365, COSV60373024; called by muse, mutect2, varscan2
- MAEL | c.753G>A p.G251= | Silent (SNP) | VAF 11/339 reads (3%) | catalogued as rs942545696, COSV63112300, COSV63112673; called by muse, mutect2
- MUC16 | c.14616T>C p.I4872= | Silent (SNP) | VAF 128/303 reads (42%) | called by muse, mutect2
- NLGN4Y | c.588C>T p.V196= | Silent (SNP) | VAF 21/158 reads (13%) | called by muse, mutect2, varscan2
- OR12D1 | c.6G>A p.L2= | Silent (SNP) | VAF 10/165 reads (6%) | called by muse, mutect2
- PCDHGA5 | c.678G>A p.T226= | Silent (SNP) | VAF 56/403 reads (14%) | catalogued as COSV54035920; called by muse, mutect2, varscan2
- PRICKLE2 | c.231G>A p.Q77= (on ENST00000295902; = p.Q21= on NM_198859.4) | Silent (SNP) | VAF 38/572 reads (7%) | called by muse, mutect2
- TENM2 | c.2691C>T p.P897= (on ENST00000518659 / NM_001122679.2; = p.P665= on NM_001080428.3) | Silent (SNP) | VAF 143/336 reads (43%) | catalogued as rs751961255, COSV69139448; called by muse, mutect2, varscan2
- ZNF827 | c.1542G>A p.G514= | Silent (SNP) | VAF 24/463 reads (5%) | called by muse, mutect2
